Somatic mutation profile of tumor specimen TCGA-34-5239-01A (aliquot TCGA-34-5239-01A-21D-1817-08) from TCGA case TCGA-34-5239, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 75.4 years (27,528 days).
Specimen TCGA-34-5239-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf84d817-a5bd-427a-ae69-cac9d9206ad7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5239-10A (Blood Derived Normal), aliquot TCGA-34-5239-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c4b4a0-0223-4576-a3dd-33c2ed51b997

The open-access MAF lists 256 somatic variants for this specimen: 203 protein-altering or splice-affecting, 48 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 48, Splice Site 9, Nonsense Mutation 8, Frame Shift Ins 4, Splice Region 4, Frame Shift Del 4, Intron 3, RNA 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN1 | c.2201A>G p.Q734R | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as rs1555343284, COSV51989233; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PROM1 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs780697796, CM153058, COSV71699208; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 51/104 reads (49%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- TTN | c.102332G>A p.R34111H (on ENST00000591111; = p.R26687H on NM_003319.4) | Missense Mutation (SNP) | VAF 39/96 reads (41%) | PolyPhen probably damaging (0.933); catalogued as rs760107623, COSV59931607; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.4057G>T p.V1353L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62321750; called by muse, mutect2
- ACTN2 | c.362A>C p.E121A | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV63973076; called by muse, mutect2, varscan2
- ACVR1C | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429636849, COSV54644467; called by muse, mutect2, varscan2
- ADAM20 | c.772G>C p.D258H | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV56454303; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV57860213; called by muse, mutect2, varscan2
- ADCY1 | c.2162C>A p.T721N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52031560; called by muse, mutect2, varscan2
- ADGRG3 | c.1357G>A p.V453M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59650429; called by muse, mutect2, varscan2
- ADGRL4 | c.1665T>A p.Y555* | Nonsense Mutation (SNP) | VAF 33/195 reads (17%) | catalogued as COSV66060002; called by muse, mutect2, varscan2
- ALDH9A1 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 86/219 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1024946102, COSV61339298; called by muse, mutect2, varscan2
- ALPK2 | c.5820C>G p.H1940Q | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV64490990, COSV64492577; called by muse, mutect2, varscan2
- ANKRD34A | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.99); PolyPhen benign (0.084); catalogued as COSV60160396; called by muse, mutect2, varscan2
- ATP11B | c.3128C>T p.S1043F | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV60026882; called by muse, mutect2, varscan2
- ATP8B2 | c.604G>A p.D202N (on ENST00000672630; = p.D169N on NM_001005855.2) | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59245162; called by muse, mutect2, varscan2
- ATXN7L1 | c.103A>G p.K35E | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs1475508500, COSV59491885; called by muse, mutect2, varscan2
- B3GAT2 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57769220, COSV57769579; called by muse, mutect2, varscan2
- BBS9 | c.1749A>T p.L583F (on ENST00000242067 / NM_001348036.1; = p.L543F on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.196); catalogued as COSV54159708; called by muse, mutect2, varscan2
- BCORL1 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1199456475, COSV54391416; called by muse, mutect2, varscan2
- BIRC6 | c.3752A>T p.H1251L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV70196656; called by muse, mutect2, varscan2
- BPI | c.1127C>A p.A376D (on ENST00000262865; = p.A372D on NM_001725.3) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53404322; called by muse, mutect2, varscan2
- BRINP3 | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.075); catalogued as COSV66512795, COSV66516022; called by muse, mutect2, varscan2
- CA7 | c.731T>A p.V244E | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV58156126; called by muse, mutect2, varscan2
- CAD | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV53024466; called by muse, mutect2, varscan2
- CADPS | c.1194C>A p.F398L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV51870991; called by muse, mutect2, varscan2
- CASR | c.1577T>C p.I526T (on ENST00000490131; = p.I603T on NM_000388.4) | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.669); catalogued as COSV56135288; called by muse, mutect2, varscan2
- CCDC180 | c.4900C>T p.Q1634* | Nonsense Mutation (SNP) | VAF 47/84 reads (56%) | catalogued as COSV63827720; called by muse, mutect2, varscan2
- CD248 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV60935926; called by muse, mutect2, varscan2
- CDH20 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.671); catalogued as COSV53006070; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1289G>T p.R430I (on ENST00000357886 / NM_001365728.1; = p.R416I on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV59426188; called by muse, mutect2, varscan2
- CECR2 | c.923A>G p.D308G (on ENST00000342247 / NM_001290047.2; = p.D145G on NM_001290046.1) | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV52837673; called by muse, mutect2, varscan2
- CECR2 | c.1858G>A p.E620K (on ENST00000342247 / NM_001290047.2; = p.E437K on NM_001290046.1) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV52837686, COSV52848843; called by muse, mutect2, varscan2
- CEP192 | c.6191G>A p.R2064K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV58061101; called by muse, mutect2, varscan2
- COL11A1 | c.4844C>A p.P1615H | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV62175654; called by muse, mutect2, varscan2
- COL5A1 | c.2475G>T p.K825N | Missense Mutation (SNP) | VAF 180/273 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65666370; called by muse, mutect2, varscan2
- COP1 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV58162848; called by muse, mutect2, varscan2
- CWH43 | c.863G>A p.C288Y | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.558); catalogued as COSV56936871; called by muse, mutect2, varscan2
- CYP2C18 | c.1329G>C p.M443I | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV53670384, COSV53671143, COSV53672129; called by muse, mutect2, varscan2
- DCAF1 | c.1029A>G p.L343= | Splice Region (SNP) | VAF 9/16 reads (56%) | catalogued as rs782129844, COSV60041283; called by muse, mutect2, varscan2
- DDX54 | c.1719G>T p.A573= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV58372361, COSV58376412; called by muse, mutect2, varscan2
- DNAJC6 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54771291; called by muse, mutect2, varscan2
- DSG4 | c.2924C>A p.P975H | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.524); catalogued as COSV57389084, COSV57389150; called by muse, mutect2, varscan2
- EIF3E | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs762481715, COSV55201909; called by muse, mutect2, varscan2
- ERICH3 | c.2742G>T p.E914D | Missense Mutation (SNP) | VAF 42/277 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV58601600; called by muse, mutect2, varscan2
- ERN2 | c.1200G>T p.L400F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV56832118; called by muse, mutect2, varscan2
- ESPNL | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.596); catalogued as COSV58032956; called by muse, mutect2, varscan2
- ETNPPL | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV56594370; called by muse, mutect2, varscan2
- EXOC4 | c.1091A>T p.Q364L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV54087678, COSV54102901; called by muse, mutect2, varscan2
- FAHD2B | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.302); catalogued as COSV55630142; called by muse, mutect2, varscan2
- FAM135B | c.2782G>T p.G928C | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs1208370643, COSV52711528; called by muse, mutect2, varscan2
- FAM3C | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63435057; called by muse, mutect2, varscan2
- FAM47C | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.155); catalogued as COSV63724542; called by muse, mutect2, varscan2
- FAM71B | c.995G>C p.G332A | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as COSV57227983; called by muse, mutect2
- FCGR2B | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV52680933; called by muse, mutect2, varscan2
- FSHR | c.1527C>A p.S509R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58619505; called by muse, mutect2, varscan2
- GCNT1 | c.469A>G p.K157E | Missense Mutation (SNP) | VAF 109/142 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057031; called by muse, mutect2, varscan2
- GDNF | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV58478657; called by muse, mutect2, varscan2
- GNB5 | c.901G>A p.D301N (on ENST00000261837 / NM_016194.4; = p.D259N on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV55898191; called by muse, mutect2
- GP2 | c.622G>T p.G208C (on ENST00000381362 / NM_001007240.3; = p.G205C on NM_001502.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.572); catalogued as COSV56892465; called by muse, mutect2, varscan2
- GPC3 | c.335A>C p.Q112P | Missense Mutation (SNP) | VAF 79/135 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV63660397; called by muse, mutect2, varscan2
- GRIN2A | c.2536C>A p.R846S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58018457, COSV58033091; called by muse, mutect2, varscan2
- GRM8 | c.1957G>C p.V653L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV58809992; called by muse, mutect2, varscan2
- IFI44 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV66074249; called by muse, mutect2, varscan2
- IGBP1P2 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 296/512 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs766559048; called by muse, mutect2, varscan2
- IGHMBP2 | c.2879C>T p.S960F | Missense Mutation (SNP) | VAF 118/187 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV54820690; called by muse, varscan2
- INMT | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV50000444; called by muse, mutect2, varscan2
- INTS1 | c.2456A>G p.K819R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV67176645; called by muse, mutect2, varscan2
- IPO11 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57573173; called by muse, mutect2, varscan2
- IQUB | c.12A>T p.Q4H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as COSV61237825; called by muse, mutect2, varscan2
- JAK3 | c.2059A>G p.R687G | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71685782; called by muse, mutect2, varscan2
- JPT2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.069); catalogued as COSV50188581; called by muse, mutect2, varscan2
- KCNN2 | c.605C>A p.A202E (on ENST00000264773; = p.A414E on NM_021614.4) | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53284779, COSV99300175; called by muse, mutect2, varscan2
- KIF2B | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52127904; called by muse, mutect2, varscan2
- KMT2C | c.4828G>C p.D1610H | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV51403340; called by muse, mutect2, varscan2
- LAMA2 | c.2848A>G p.K950E | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV70341515; called by muse, mutect2
- LGALS13 | c.361G>C p.V121L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1256516130, COSV55679530; called by muse, mutect2, varscan2
- LILRA1 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV52178951, COSV52185765; called by muse, varscan2
- LINC02210-CRHR1 | c.220G>T p.G74W | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53276312; called by muse, mutect2, varscan2
- LRRC7 | c.712-1G>A p.X238_splice (on ENST00000651989 / NM_001370785.2; = p.X205_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 41/192 reads (21%) | catalogued as COSV50420325, COSV99226266; called by muse, mutect2, varscan2
- LRRC7 | c.797A>T p.K266M (on ENST00000651989 / NM_001370785.2; = p.K233M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV50420398; called by muse, mutect2, varscan2
- LRRIQ4 | c.220A>G p.R74G | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV61618815; called by muse, mutect2, varscan2
- LRRK2 | c.6838G>A p.V2280I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100109547, COSV54146884; called by muse, mutect2, varscan2
- LYPD1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.367); catalogued as COSV58432567; called by muse, mutect2
- LYSMD1 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748958647, COSV64419936; called by muse, mutect2, varscan2
- MACF1 | c.17986T>C p.F5996L (on ENST00000372915; = p.F4041L on NM_012090.5) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV57110565; called by muse, mutect2, varscan2
- MAGEC1 | c.2734G>T p.V912L | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV53569426; called by muse, mutect2, varscan2
- MC5R | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV61254095; called by muse, mutect2, varscan2
- MIDN | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV56294041, COSV56294832; called by muse, mutect2, varscan2
- MTOR | c.6814G>T p.A2272S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV63869147; called by muse, mutect2, varscan2
- MTTP | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV55504431; called by muse, mutect2, varscan2
- MUC15 | c.821T>A p.L274H | Missense Mutation (SNP) | VAF 53/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55553312; called by muse, mutect2, varscan2
- MUC16 | c.34782C>G p.N11594K | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67452194, COSV67464043; called by muse, mutect2, varscan2
- MUC16 | c.6591C>G p.N2197K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV67452201; called by muse, mutect2, varscan2
- MUC5B | c.6116C>G p.P2039R | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.452); catalogued as COSV71590493; called by muse, mutect2, varscan2
- MYH13 | c.2296A>T p.K766* | Nonsense Mutation (SNP) | VAF 35/65 reads (54%) | catalogued as COSV52822598; called by muse, mutect2, varscan2
- N4BP1 | c.2535G>T p.M845I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV52209893; called by muse, mutect2, varscan2
- NBEA | c.5950G>T p.E1984* | Nonsense Mutation (SNP) | VAF 50/88 reads (57%) | catalogued as COSV59766978; called by muse, mutect2, varscan2
- NCKAP1L | c.335T>G p.I112S | Missense Mutation (SNP) | VAF 66/213 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53204382; called by muse, mutect2, varscan2
- NDUFB7 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV53107825; called by muse, mutect2, varscan2
- NEB | c.5563G>T p.D1855Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50845447; called by muse, mutect2, varscan2
- NEUROD4 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.201); catalogued as COSV54470820; called by muse, mutect2, varscan2
- NFE2L3 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV50226230, COSV50226506; called by muse, mutect2
- NHS | c.422A>T p.D141V | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV66272457; called by muse, mutect2, varscan2
- NLRP13 | c.2129C>A p.S710Y | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV61620552; called by muse, mutect2, varscan2
- OR10AG1 | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56631961, COSV56635529; called by muse, mutect2, varscan2
- OR4N2 | c.679G>T p.G227W | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV60050416; called by muse, mutect2, varscan2
- OR4Q3 | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59177621, COSV59178508; called by muse, mutect2, varscan2
- OR5F1 | c.926G>T p.R309M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs760087160, COSV53545680; called by muse, mutect2, varscan2
- OR5M1 | c.592del p.A198Qfs*4 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as COSV73202087; called by mutect2, varscan2
- OR6C75 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV58551526; called by muse, mutect2, varscan2
- OR6X1 | c.435C>A p.S145R | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV60009478; called by muse, mutect2, varscan2
- OR8B8 | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV60144051; called by muse, mutect2, varscan2
- OR9G4 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV57247664, COSV57248021; called by muse, mutect2, varscan2
- OSBP2 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV60240624; called by muse, mutect2, varscan2
- PCDHA7 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100971251; called by mutect2, varscan2
- PCDHGA2 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53912789; called by muse, mutect2, varscan2
- PDYN | c.247G>T p.G83W | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs927079566, COSV54101145; called by muse, mutect2, varscan2
- PDYN | c.246G>T p.L82F | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.235); catalogued as COSV54101157; called by muse, mutect2, varscan2
- PIK3C3 | c.1606A>T p.R536* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | catalogued as COSV56276843; called by muse, varscan2
- PIK3CG | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63246545; called by muse, mutect2, varscan2
- PKN1 | c.1936C>G p.L646V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52874617; called by muse, mutect2, varscan2
- POLE | c.2865G>T p.R955S | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100265387; called by mutect2, varscan2
- POLE | c.2865-1G>T p.X955_splice | Splice Site (SNP) | VAF 30/136 reads (22%) | catalogued as COSV57683989; called by mutect2, varscan2
- PREX2 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55756996; called by muse, mutect2, varscan2
- PRTG | c.2153T>A p.M718K | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV66837123, COSV66837428; called by muse, mutect2, varscan2
- RB1CC1 | c.2149G>A p.V717I | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV50243813, COSV50254809; called by muse, mutect2, varscan2
- REG3A | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100532643, COSV100532800, COSV59408769; called by muse, mutect2, varscan2
- RIPK2 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55131866, COSV99609824; called by muse, mutect2
- RIPOR3 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs370389293; called by muse, mutect2, varscan2
- RLIM | c.1177G>T p.G393C | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60325602; called by muse, mutect2, varscan2
- ROBO1 | c.309A>C p.K103N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71392433; called by muse, mutect2, varscan2
- RPL3L | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV51905649; called by muse, mutect2
- RYBP | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV72180231; called by muse, mutect2, varscan2
- RYR2 | c.10839G>T p.R3613S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV63669863; called by muse, mutect2, varscan2
- SCN1A | c.6014A>C p.K2005T (on ENST00000303395 / NM_001202435.3; = p.K1994T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV57663352; called by muse, varscan2
- SCN1A | c.5929A>G p.M1977V (on ENST00000303395 / NM_001202435.3; = p.M1966V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as CM121771, COSV57663368; called by muse, varscan2
- SCN3A | c.3669G>A p.L1223= | Splice Region (SNP) | VAF 17/98 reads (17%) | catalogued as COSV51804316; called by muse, mutect2, varscan2
- SCUBE1 | c.1169C>A p.P390Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs185039637, COSV62610643, COSV62612574; called by muse, mutect2
- SEMA6D | c.995G>C p.S332T | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV60374049, COSV60379242; called by muse, mutect2
- SESN2 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53426926; called by muse, mutect2, varscan2
- SH3BP4 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60642782; called by muse, mutect2, varscan2
- SHKBP1 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753952010, COSV52538099; called by muse, mutect2, varscan2
- SIGLEC1 | c.3892G>A p.G1298S | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.297); catalogued as rs761343460, COSV52460120; called by muse, mutect2, varscan2
- SLAMF9 | c.406C>G p.P136A | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV63636358; called by muse, mutect2, varscan2
- SLC26A8 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV62884951; called by muse, mutect2, varscan2
- SLC35F5 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV55517275; called by muse, mutect2, varscan2
- SLC4A4 | c.1262A>G p.H421R (on ENST00000264485 / NM_001098484.3; = p.H377R on NM_003759.4) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs370710771; called by muse, mutect2, varscan2
- SLCO1B1 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57008244; called by muse, mutect2, varscan2
- SNAPC4 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV53731383; called by muse, mutect2, varscan2
- SORCS1 | c.1065G>T p.E355D | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV53848301; called by muse, mutect2, varscan2
- SPATA16 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV63527485; called by muse, mutect2, varscan2
- SPEG | c.3011G>T p.R1004L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV56665005; called by muse, mutect2, varscan2
- SPESP1 | c.920G>T p.R307I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52985968; called by muse, mutect2, varscan2
- SS18L1 | c.721+1G>T p.X241_splice | Splice Site (SNP) | VAF 13/28 reads (46%) | catalogued as COSV59209493; called by muse, mutect2, varscan2
- ST18 | c.862G>C p.V288L | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs947153497, COSV52487414; called by muse, mutect2, varscan2
- ST6GAL2 | c.1403A>G p.Y468C | Missense Mutation (SNP) | VAF 13/68 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV62416074; called by muse, mutect2, varscan2
- STARD13 | c.512C>T p.S171L (on ENST00000336934 / NM_001243476.3; = p.S53L on NM_052851.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV55228161; called by muse, mutect2, varscan2
- STK31 | c.151-2A>G p.X51_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV63454580; called by muse, mutect2
- TEX9 | c.274C>G p.P92A | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV61877247; called by muse, mutect2
- TGM5 | c.2106C>G p.S702R (on ENST00000220420 / NM_201631.4; = p.S620R on NM_004245.4) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55009006; called by muse, mutect2, varscan2
- TGM6 | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.883); catalogued as COSV52478050; called by muse, mutect2, varscan2
- TMEM107 | c.88-1G>T p.X30_splice | Splice Site (SNP) | VAF 40/78 reads (51%) | catalogued as COSV57100892; called by muse, mutect2, varscan2
- TMPRSS15 | c.2261+1G>T p.X754_splice | Splice Site (SNP) | VAF 9/66 reads (14%) | catalogued as COSV53036151; called by muse, varscan2
- TNN | c.1235-1G>T p.X412_splice | Splice Site (SNP) | VAF 9/28 reads (32%) | catalogued as rs770161160, COSV53422899, COSV53425150; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.2459A>T p.Q820L | Missense Mutation (SNP) | VAF 97/384 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); catalogued as COSV61454563; called by muse, mutect2, varscan2
- TRPM2 | c.1664G>T p.R555L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as rs762386651, COSV55967101, COSV55969972; called by muse, mutect2
- TTLL7 | c.1000G>T p.G334* | Nonsense Mutation (SNP) | VAF 23/160 reads (14%) | catalogued as COSV53082132; called by muse, mutect2, varscan2
- TTN | c.47322C>A p.D15774E (on ENST00000591111; = p.D8350E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | PolyPhen benign (0.003); catalogued as COSV59931642; called by muse, mutect2, varscan2
- TTN | c.7720C>A p.P2574T (on ENST00000591111; = p.P2528T on NM_003319.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | PolyPhen benign (0.053); catalogued as COSV59931673; called by muse, mutect2, varscan2
- UBASH3B | c.1450+1G>A p.X484_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as rs1399771298, COSV52491532; called by muse, mutect2, varscan2
- USH2A | c.4981G>T p.D1661Y | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV56339007; called by muse, mutect2, varscan2
- USP6NL | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53209737; called by muse, mutect2, varscan2
- VAV1 | c.702G>T p.E234D | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100408684, COSV58380098; called by muse, mutect2, varscan2
- VPS13B | c.3366G>C p.K1122N | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs752453891, COSV62135828; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VRK1 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV53708342; called by muse, mutect2, varscan2
- VWA3A | c.3341del p.P1114Lfs*14 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs767167126; called by mutect2, pindel, varscan2
- WDR17 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.079); catalogued as COSV54568163, COSV54570046; called by muse, mutect2, varscan2
- YLPM1 | c.4420C>G p.Q1474E | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.208); catalogued as COSV53107719; called by muse, mutect2
- ZAN | c.4824C>A p.D1608E | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV61806351; called by muse, mutect2, varscan2
- ZDBF2 | c.2345G>T p.S782I | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV65622850; called by muse, mutect2, varscan2
- ZFP37 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 112/181 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65286105; called by muse, mutect2, varscan2
- ZFP37 | c.1147G>T p.G383W | Missense Mutation (SNP) | VAF 114/183 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65286118; called by muse, mutect2, varscan2
- ZNF114 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV59943756; called by muse, mutect2, varscan2
- ZNF229 | c.2069G>T p.G690V | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52160429; called by muse, mutect2, varscan2
- ZNF236 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.575); catalogued as COSV53483955; called by muse, mutect2, varscan2
- ZNF479 | c.165G>T p.L55= | Splice Region (SNP) | VAF 31/167 reads (19%) | catalogued as COSV100482337, COSV58636091; called by muse, mutect2, varscan2
- ZNF566 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV67573359; called by muse, mutect2, varscan2
- ZNF709 | c.54G>T p.W18C | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67194304, COSV67196188; called by muse, mutect2, varscan2
- ZNF93 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59374476; called by muse, mutect2, varscan2
- ZNRF4 | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55773205; called by muse, mutect2
- ZP4 | c.1258T>G p.F420V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.348); catalogued as COSV63911340; called by muse, mutect2, varscan2
- ZWINT | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59185017; called by muse, mutect2, varscan2
- COL11A2 | c.2690del p.P897Lfs*87 (on ENST00000341947 / NM_080680.3; = p.P790Lfs*87 on NM_080679.2) | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- FOLH1 | c.236dup p.I80Dfs*30 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- FOLH1 | c.235delinsAA p.Q79Kfs*31 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | called by mutect2*, pindel, varscan2*
- IGKV3-15 | c.266C>G p.T89R | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- PIK3R2 | c.1856_1866del p.E619Vfs*188 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel
- TOR1AIP1 | c.530_531insG p.R178Qfs*10 | Frame Shift Ins (INS) | VAF 19/79 reads (24%) | called by mutect2, pindel*, varscan2
- TRAF2 | c.1028_1054del p.L343_G352delinsW | In Frame Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- VCX3B | c.199dup p.A67Gfs*? | Frame Shift Ins (INS) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- VPS13B | c.9150_9152dup p.T3051dup | In Frame Ins (INS) | VAF 58/120 reads (48%) | called by mutect2, pindel, varscan2
- ABCA1 | c.6294G>A p.V2098= | Silent (SNP) | VAF 84/149 reads (56%) | catalogued as rs776855188, COSV66064461; called by muse, mutect2, varscan2
- ACSM2A | c.495A>G p.Q165= (on ENST00000219054; = p.Q86= on NM_001308169.2) | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as rs1378100560, COSV54583014; called by muse, mutect2, varscan2
- ADAMTS6 | c.2847C>A p.V949= | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV58681937; called by muse, mutect2, varscan2
- AGPAT3 | c.720G>A p.L240= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV52368514; called by muse, mutect2, varscan2
- AGPAT4 | c.231G>A p.T77= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs768116636, COSV57243718; called by muse, mutect2, varscan2
- AMER3 | c.894C>A p.P298= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs140458255, COSV58465585; called by muse, mutect2, varscan2
- C2orf42 | c.489G>T p.P163= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100033694; called by muse, mutect2, varscan2
- CCKBR | c.759C>T p.G253= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV58099392; called by muse, mutect2, varscan2
- CDH12 | c.42G>T p.L14= | Silent (SNP) | VAF 97/285 reads (34%) | catalogued as rs899518674, COSV101201287, COSV66392947; called by muse, mutect2, varscan2
- CLCN2 | c.1050G>C p.R350= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV55599908; called by muse, mutect2, varscan2
- CLEC4F | c.123C>T p.T41= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV55478528; called by muse, mutect2, varscan2
- COLQ | c.912C>T p.Y304= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as rs886058099, COSV67524247; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- COPRS | c.510C>T p.S170= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs767822266, COSV56632556; called by muse, mutect2, varscan2
- COQ5 | c.231G>A p.K77= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV56018520; called by muse, mutect2, varscan2
- CST4 | c.96T>A p.G32= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV54149289; called by muse, mutect2, varscan2
- CYP2A13 | c.171C>A p.S57= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV57836732; called by muse, mutect2, varscan2
- DCAF4L2 | c.738G>T p.G246= | Silent (SNP) | VAF 68/120 reads (57%) | catalogued as COSV60477109; called by muse, mutect2, varscan2
- DUSP18 | c.51C>T p.V17= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV58180803; called by muse, mutect2, varscan2
- FBN3 | c.8295G>T p.R2765= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV53663888; called by muse, mutect2, varscan2
- FCRL5 | c.354T>C p.S118= | Silent (SNP) | VAF 51/132 reads (39%) | catalogued as rs1191829931, COSV62512560; called by muse, mutect2, varscan2
- FIBIN | c.426C>T p.S142= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV59412538; called by muse, mutect2, varscan2
- GEMIN7 | c.207C>T p.S69= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV54319286; called by muse, mutect2, varscan2
- GPRC6A | c.2634C>G p.V878= | Silent (SNP) | VAF 63/116 reads (54%) | catalogued as COSV59952049; called by muse, mutect2, varscan2
- GRM5 | c.2124C>A p.I708= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV59595310, COSV59599251; called by muse, mutect2, varscan2
- HIP1 | c.141C>T p.A47= | Silent (SNP) | VAF 34/197 reads (17%) | catalogued as COSV61183995; called by muse, mutect2, varscan2
- ICE1 | c.5886A>C p.T1962= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV56820761; called by muse, mutect2, varscan2
- KIR3DL1 | c.777G>T p.G259= | Silent (SNP) | VAF 59/246 reads (24%) | catalogued as COSV100428259; called by muse, varscan2
- KLHL40 | c.1080G>A p.Q360= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV55133208; called by muse, mutect2, varscan2
- LRP1B | c.2973C>T p.D991= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs745554983, COSV67196448; called by muse, mutect2, varscan2
- LRRTM4 | c.1461C>T p.D487= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs759609884, COSV69139311; called by muse, mutect2, varscan2
- MUC16 | c.16581C>T p.S5527= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV101198188, COSV67452197; called by muse, mutect2, varscan2
- MYLK3 | c.630A>T p.S210= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV67362936; called by muse, mutect2, varscan2
- NEUROD1 | c.276T>A p.T92= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV54548423, COSV99716937; called by muse, mutect2, varscan2
- NME1 | c.378A>G p.A126= | Silent (SNP) | VAF 72/122 reads (59%) | catalogued as COSV50147079; called by muse, mutect2, varscan2
- PAPPA2 | c.1878G>A p.G626= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV62774659; called by muse, mutect2, varscan2
- PNPLA3 | c.399G>T p.R133= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV53377521; called by muse, mutect2, varscan2
- PSMB4 | c.381C>T p.S127= | Silent (SNP) | VAF 22/246 reads (9%) | catalogued as COSV51850708; called by muse, mutect2
- PTPRZ1 | c.2016C>T p.S672= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV66432176; called by muse, mutect2, varscan2
- REPS2 | c.1011G>T p.L337= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV58179967; called by muse, mutect2, varscan2
- SIGLEC14 | c.852G>T p.L284= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV55778061; called by muse, mutect2, varscan2
- SLC5A11 | c.1746C>T p.N582= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs758998102, COSV61740532; called by muse, mutect2, varscan2
- SNAP91 | c.6G>T p.S2= | Silent (SNP) | VAF 29/46 reads (63%) | catalogued as COSV52117548; called by muse, mutect2, varscan2
- STAB2 | c.1827G>A p.R609= | Silent (SNP) | VAF 36/165 reads (22%) | catalogued as COSV66335755; called by muse, mutect2, varscan2
- TBX2 | c.1074G>C p.A358= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs1487409336, COSV53598193, COSV99538624; called by muse, varscan2
- UPP1 | c.630C>G p.T210= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV57977224; called by muse, mutect2, varscan2
- YIPF7 | c.252G>T p.S84= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV60656235; called by muse, mutect2, varscan2
- ZNF517 | c.1104C>T p.H368= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs779341729, COSV63464585; called by muse, mutect2, varscan2
- ZNF8 | c.1632A>G p.Q544= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV52186773; called by muse, mutect2, varscan2
- MAP3K19 | c.3222+475G>C | Intron (SNP) | VAF 58/142 reads (41%) | catalogued as COSV100208073, COSV100208317; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85364G>T | Intron (SNP) | VAF 23/40 reads (58%) | catalogued as COSV72275725; called by muse, mutect2, varscan2
- MIR1269A | n.8C>A | RNA (SNP) | VAF 85/172 reads (49%) | called by muse, mutect2, varscan2
- RPS26P15 | n.82C>T | RNA (SNP) | VAF 21/101 reads (21%) | catalogued as rs753782346; called by muse, mutect2, varscan2
- TMEM71 | c.814+158C>A | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs577561745, COSV63458731; called by muse, mutect2, varscan2
